Somatic mutation profile of tumor specimen 21880d70-69eb-4f09-bea9-8de3e6 (aliquot 21880d70-69eb-4f09-bea9-8de3e6_D7_1) from CPTAC case 05CO005, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I.
Specimen 21880d70-69eb-4f09-bea9-8de3e6: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86610fb6-9121-44a4-9a31-fae67a46ce71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen c8b34c3b-89de-4f3d-a1af-c06f5a (Blood Derived Normal), aliquot c8b34c3b-89de-4f3d-a1af-c06f5a_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d170af38-3c22-479c-947a-0c6cee3ab45b

The open-access MAF lists 149 somatic variants for this specimen: 103 protein-altering or splice-affecting, 31 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 31, Nonsense Mutation 7, Intron 6, 3'UTR 4, Splice Region 3, Splice Site 2, RNA 2, Frame Shift Ins 2, Frame Shift Del 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 42/128 reads (33%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, varscan2
- SCN1A | c.4786C>T p.R1596C (on ENST00000303395 / NM_001202435.3; = p.R1585C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121917993, CM071991, COSV57683326; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- ACD | c.902C>T p.T301M (on ENST00000620338; = p.T212M on NM_022914.3) | Missense Mutation (SNP) | VAF 108/338 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs72547495; ClinVar: uncertain significance; called by muse, varscan2
- ADAMTS2 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 97/402 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376707472, COSV52390258; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS7 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs372048232; called by muse, mutect2, varscan2
- AK5 | c.1318G>A p.V440I (on ENST00000354567 / NM_174858.3; = p.V414I on NM_012093.4) | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs759165576, COSV60970735; called by muse, mutect2, varscan2
- APBA2 | c.1781C>T p.T594M | Missense Mutation (SNP) | VAF 109/367 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747910571, COSV101258186; called by muse, mutect2, varscan2
- APC | c.4037C>A p.S1346* | Nonsense Mutation (SNP) | VAF 59/292 reads (20%) | catalogued as COSV57325995, COSV57328373, COSV57364395; called by muse, mutect2, varscan2
- ARHGAP23 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 12/319 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs751152407; called by muse, mutect2
- ASAP1 | c.1008C>T p.D336= | Splice Region (SNP) | VAF 23/75 reads (31%) | catalogued as rs747363071, COSV63047144; called by muse, mutect2, varscan2
- ATP13A1 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.028); catalogued as rs143627291; called by muse, mutect2, varscan2
- BTN2A1 | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372666428, COSV100438634; called by muse, mutect2, varscan2
- CALN1 | c.247C>T p.R83C (on ENST00000329008 / NM_001017440.3; = p.R125C on NM_031468.4) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs758325177, COSV61118287; called by muse, mutect2, varscan2
- CCDC171 | c.3143G>A p.R1048Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as rs750226400, COSV52654189; called by mutect2, varscan2
- CDC42BPB | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs367791222; called by muse, mutect2, varscan2
- CEP128 | c.2387_2388del p.I796Kfs*3 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | catalogued as rs752969645; called by pindel, varscan2
- CHRDL1 | c.1019C>T p.T340M (on ENST00000372045; = p.T346M on NM_145234.4) | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs759525550, COSV104373392; called by muse, mutect2, varscan2
- CILP2 | c.3067G>A p.V1023I | Missense Mutation (SNP) | VAF 123/427 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as rs751155853, COSV99365098; called by muse, mutect2, varscan2
- CPNE1 | c.714G>A p.P238= (on ENST00000352393; = p.P243= on NM_003915.5) | Splice Region (SNP) | VAF 139/286 reads (49%) | catalogued as rs761281950; called by muse, mutect2, varscan2
- CTNNA3 | c.2177A>G p.K726R | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV101041185; called by muse, mutect2, varscan2
- DACH2 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 48/66 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs770481654, COSV64165249; called by muse, mutect2, varscan2
- DOCK10 | c.4385C>T p.T1462I | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as rs943767040; called by muse, mutect2, varscan2
- DPPA4 | c.383A>G p.N128S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.185); catalogued as rs776933550; called by muse, mutect2, varscan2
- DYNC2I1 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs760864089, COSV101337652; called by muse, mutect2, varscan2
- EIF2S3B | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 133/380 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); catalogued as rs746895233; called by muse, mutect2, varscan2
- FAM47B | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 127/176 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV61455930; called by muse, mutect2, varscan2
- GDAP1L1 | c.278A>T p.N93I | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100697606; called by muse, mutect2, varscan2
- HERC2 | c.6796G>A p.V2266M | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs777318947; called by muse, mutect2, varscan2
- HRH4 | c.1022G>C p.R341T | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV56928912; called by muse, mutect2, varscan2
- IGHG4 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 88/338 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs374177525; called by muse, mutect2, varscan2
- LHFPL6 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs781744229, COSV101095532; called by muse, varscan2
- MAST4 | c.3203G>A p.R1068Q (on ENST00000403625 / NM_001164664.2; = p.R879Q on NM_015183.3) | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764447226, COSV104375399; called by muse, mutect2, varscan2
- MCAM | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 48/302 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.735); catalogued as rs755944376, COSV50670780, COSV99875369; called by muse, mutect2, varscan2
- MIEN1 | c.202_207del p.E68_I69del | In Frame Del (DEL) | VAF 41/268 reads (15%) | catalogued as rs1309417265; called by pindel, varscan2
- MOV10 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 63/208 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs558568709; called by muse, mutect2, varscan2
- MRPS5 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 18/190 reads (9%) | catalogued as rs746219247, COSV55535730; called by muse, mutect2
- MUC16 | c.13908G>A p.M4636I | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV101200335; called by muse, mutect2, varscan2
- MYBPC3 | c.3742G>C p.G1248R | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); catalogued as CM081703, COSV57023917, COSV57025326; called by muse, mutect2, varscan2
- MYO15A | c.6710C>T p.P2237L | Missense Mutation (SNP) | VAF 126/330 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs1244175690; called by muse, mutect2, varscan2
- NCAM1 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555113023; called by muse, mutect2, varscan2
- NOS3 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); catalogued as rs139184126; called by muse, mutect2, varscan2
- NUDT6 | c.443-1G>A p.X148_splice | Splice Site (SNP) | VAF 29/118 reads (25%) | catalogued as COSV100193839; called by muse, mutect2, varscan2
- OR2G6 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 96/314 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs375204402, COSV58573740; called by muse, mutect2, varscan2
- OR2T33 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 144/783 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs139302289, COSV100532243; called by muse, varscan2
- PHLPP2 | c.3673G>A p.E1225K | Missense Mutation (SNP) | VAF 76/548 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.651); catalogued as rs1474867444; called by muse, mutect2, varscan2
- PP2D1 | c.612dup p.G205Wfs*4 | Frame Shift Ins (INS) | VAF 30/110 reads (27%) | catalogued as rs550751104; called by mutect2, varscan2
- PRB3 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs78040729; called by muse, varscan2
- PTPRC | c.3645+1G>A p.X1215_splice | Splice Site (SNP) | VAF 27/107 reads (25%) | catalogued as rs1284216509, COSV61411675; called by muse, mutect2, varscan2
- RBM10 | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 70/102 reads (69%) | catalogued as COSV61309256, COSV61309471; called by muse, mutect2, varscan2
- SCN2A | c.4259C>T p.T1420M | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1382026643, CM161415, COSV99331626; called by muse, mutect2, varscan2
- SCN4A | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs897448432, COSV71125722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3D19 | c.975G>A p.P325= | Splice Region (SNP) | VAF 6/31 reads (19%) | catalogued as rs113012255, COSV58794039; called by muse, mutect2, varscan2
- SLC13A4 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs930393636; called by muse, mutect2, varscan2
- SOX5 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs745428574, COSV58621446; called by muse, mutect2, varscan2
- SUGP1 | c.1924C>T p.R642W | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55920607; called by muse, mutect2, varscan2
- TAP2 | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs183316663, COSV66499438; called by muse, mutect2, varscan2
- TCF7L2 | c.1071C>A p.F357L (on ENST00000355995 / NM_001367943.1; = p.F334L on NM_030756.5) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53337214; called by mutect2, varscan2
- TMOD1 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs1169375821, COSV52249708; called by muse, mutect2, varscan2
- TMPRSS7 | c.922G>A p.D308N (on ENST00000452346; = p.D182N on NM_001042575.2) | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as rs367735856; called by muse, mutect2, varscan2
- TRIM64B | c.377del p.S126Tfs*3 | Frame Shift Del (DEL) | VAF 19/264 reads (7%) | catalogued as rs756697949, COSV61693556; called by mutect2, pindel
- UPK2 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs1366628202; called by muse, mutect2, varscan2
- VCX | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as COSV100406328; called by muse, varscan2
- VGLL1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.017); catalogued as rs1569362147; called by muse, mutect2
- ZC3H12C | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.181); catalogued as rs201652254, COSV53712667; called by muse, mutect2, varscan2
- ZFYVE28 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV52115052, COSV52117043; called by muse, mutect2, varscan2
- ALDH1B1 | c.1052C>G p.P351R | Missense Mutation (SNP) | VAF 95/236 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ANKZF1 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 131/424 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- B3GLCT | c.962G>C p.R321T | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- CCDC6 | c.410A>G p.E137G | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CECR2 | c.2488G>T p.D830Y (on ENST00000342247 / NM_001290047.2; = p.D647Y on NM_001290046.1) | Missense Mutation (SNP) | VAF 120/388 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- COX11 | c.106C>A p.L36I | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CREBZF | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 47/299 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- DGKA | c.758G>A p.C253Y | Missense Mutation (SNP) | VAF 76/279 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- DNAH7 | c.10043T>C p.M3348T | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT13 | c.430C>A p.H144N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GLS2 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IGBP1P2 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.9451G>A p.E3151K | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MAP2 | c.238A>T p.T80S | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MAS1L | c.755G>T p.C252F | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MCTP1 | c.1378G>T p.D460Y | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- MMP16 | c.537A>T p.K179N | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MSS51 | c.282G>A p.M94I | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- NEK2 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- NOTCH3 | c.2159G>A p.C720Y | Missense Mutation (SNP) | VAF 101/331 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2C1 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 98/351 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OR9A4 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 115/339 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- PPM1J | c.209C>A p.P70Q | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SFT2D1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2
- SLC25A3 | c.773C>G p.S258* (on ENST00000228318 / NM_005888.3; = p.S257* on NM_002635.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 58/302 reads (19%) | called by muse, varscan2
- SMAD5 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- SNCAIP | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SOGA3 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 106/343 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SOX9 | c.632C>A p.S211* | Nonsense Mutation (SNP) | VAF 135/369 reads (37%) | called by muse, mutect2, varscan2
- STAB1 | c.627_628insC p.C210Lfs*20 | Frame Shift Ins (INS) | VAF 27/152 reads (18%) | called by mutect2, pindel*, varscan2*
- SYCP1 | c.1629T>A p.N543K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIMM29 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TMEM86A | c.153G>T p.W51C | Missense Mutation (SNP) | VAF 48/413 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.055); called by mutect2, varscan2
- TRIB1 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- TTN | c.18475G>T p.D6159Y (on ENST00000591111; = p.D5232Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/152 reads (11%) | PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- TTN | c.6791G>C p.G2264A (on ENST00000591111; = p.G2218A on NM_003319.4) | Missense Mutation (SNP) | VAF 70/250 reads (28%) | PolyPhen probably damaging (0.999); called by mutect2, varscan2
- VCX3B | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.188); called by mutect2, varscan2
- XIRP2 | c.3676G>T p.E1226* (on ENST00000628543; = p.E1401* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 57/197 reads (29%) | called by muse, mutect2, varscan2
- ABCA2 | c.7308C>T p.D2436= (on ENST00000614293; = p.D2406= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 213/564 reads (38%) | catalogued as rs367773706; called by muse, mutect2, varscan2
- ANO9 | c.2211G>A p.E737= | Silent (SNP) | VAF 46/354 reads (13%) | catalogued as rs754977589; called by muse, mutect2, varscan2
- CCL3 | c.90G>A p.P30= | Silent (SNP) | VAF 20/242 reads (8%) | catalogued as rs751971057; called by muse, mutect2
- CFAP54 | c.7435C>T p.L2479= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV61573843; called by muse, mutect2, varscan2
- CHRNG | c.888T>A p.P296= | Silent (SNP) | VAF 192/654 reads (29%) | called by mutect2, varscan2
- CR1 | c.5895T>C p.C1965= | Silent (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
- CRYGD | c.192C>T p.A64= | Silent (SNP) | VAF 170/526 reads (32%) | called by muse, mutect2, varscan2
- DAZAP1 | c.1143G>A p.S381= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs368917206; called by muse, mutect2, varscan2
- EPHB1 | c.285C>T p.D95= | Silent (SNP) | VAF 106/315 reads (34%) | called by muse, mutect2, varscan2
- GPSM2 | c.543C>T p.A181= | Silent (SNP) | VAF 53/149 reads (36%) | catalogued as rs754448998, COSV99915181; called by muse, mutect2, varscan2
- HFM1 | c.256C>T p.L86= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs1557527023; called by muse, mutect2, varscan2
- ITGA9 | c.2367C>T p.D789= | Silent (SNP) | VAF 72/407 reads (18%) | catalogued as rs755375014; called by muse, mutect2, varscan2
- KALRN | c.72T>G p.S24= | Silent (SNP) | VAF 24/176 reads (14%) | called by muse, mutect2, varscan2
- KIFC3 | c.1170C>T p.R390= | Silent (SNP) | VAF 70/214 reads (33%) | catalogued as rs375424711; called by muse, mutect2, varscan2
- LHFPL6 | c.132C>T p.F44= | Silent (SNP) | VAF 64/238 reads (27%) | catalogued as rs1318574789; called by muse, varscan2
- LRCH1 | c.222G>A p.G74= | Silent (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- MACF1 | c.16629C>T p.Y5543= (on ENST00000372915; = p.Y3585= on NM_012090.5) | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs147050519; called by muse, mutect2, varscan2
- MAN2A1 | c.1644C>A p.L548= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV54852554; called by muse, mutect2, varscan2
- MAP2 | c.237G>C p.L79= | Silent (SNP) | VAF 32/128 reads (25%) | called by muse, mutect2, varscan2
- MOB4 | c.288T>C p.T96= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs1437210384; called by muse, mutect2, varscan2
- MYO5B | c.4374G>A p.T1458= | Silent (SNP) | VAF 228/528 reads (43%) | catalogued as rs373704566; called by muse, mutect2, varscan2
- NEB | c.13020T>A p.I4340= | Silent (SNP) | VAF 21/65 reads (32%) | called by mutect2, varscan2
- OR52N4 | c.813C>T p.I271= | Silent (SNP) | VAF 30/390 reads (8%) | catalogued as COSV57892335; called by muse, mutect2
- PFDN2 | c.21C>T p.R7= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as rs899970421, COSV63501151; called by muse, mutect2, varscan2
- RBPMS | c.72G>C p.R24= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV55124616; called by muse, mutect2, varscan2
- RHCG | c.939C>T p.C313= | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as rs887444040, COSV51514485; called by muse, mutect2, varscan2
- RSPH1 | c.150C>T p.F50= | Silent (SNP) | VAF 65/177 reads (37%) | catalogued as rs752263023, COSV52319757; called by muse, mutect2, varscan2
- SP140 | c.771G>A p.A257= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs760138169; called by muse, mutect2, varscan2
- TUBGCP2 | c.1881G>A p.S627= | Silent (SNP) | VAF 48/258 reads (19%) | catalogued as COSV99428381; called by muse, mutect2, varscan2
- YES1 | c.75C>T p.V25= | Silent (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- ZNF462 | c.837A>G p.Q279= | Silent (SNP) | VAF 186/439 reads (42%) | catalogued as rs1417773557; called by muse, mutect2, varscan2
- AL355390.1 | n.706G>T | RNA (SNP) | VAF 41/126 reads (33%) | called by muse, mutect2, varscan2
- AL645929.2 | chr6:29889438 G>A | 5'Flank (SNP) | VAF 41/181 reads (23%) | called by muse, mutect2, varscan2
- CCDC140 | n.873del | RNA (DEL) | VAF 5/19 reads (26%) | catalogued as rs1559326889, COSV54675823; called by mutect2, pindel, varscan2
- CD55 | c.*56T>A | 3'UTR (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- HTR3A | c.*226C>T | 3'UTR (SNP) | VAF 169/421 reads (40%) | called by muse, mutect2, varscan2
- LIG1 | c.467-17G>A | Intron (SNP) | VAF 27/120 reads (23%) | catalogued as rs548952374; called by muse, mutect2, varscan2
- MASP1 | c.1303+4985G>A | Intron (SNP) | VAF 133/412 reads (32%) | catalogued as rs140933134, COSV99961876; called by muse, mutect2, varscan2
- MRNIP | c.126+29G>A | Intron (SNP) | VAF 14/120 reads (12%) | called by muse, mutect2
- MTERF4 | c.*876G>A | 3'UTR (SNP) | VAF 19/75 reads (25%) | catalogued as rs777713504; called by muse, mutect2, varscan2
- MYL3 | chr3:46833745 C>T | 3'Flank (SNP) | VAF 65/189 reads (34%) | catalogued as rs1271231422, COSV70134108; called by muse, mutect2, varscan2
- POLR2G | c.12+23G>A | Intron (SNP) | VAF 87/181 reads (48%) | called by muse, mutect2, varscan2
- RCC1 | c.-228-70T>C | Intron (SNP) | VAF 51/113 reads (45%) | called by muse, mutect2, varscan2
- TSPY1 | c.-17G>A | 5'UTR (SNP) | VAF 94/635 reads (15%) | catalogued as COSV70474932; called by muse, varscan2
- UBP1 | c.1271+260C>T | Intron (SNP) | VAF 11/73 reads (15%) | catalogued as rs1207517051; called by muse, mutect2, varscan2
- UBR7 | c.*243G>A | 3'UTR (SNP) | VAF 115/367 reads (31%) | called by muse, mutect2, varscan2
